Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A19O, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A19O-06A (Metastatic).

PATIENT HISTORY:

Not given.

PRE-OP DIAGNOSIS: Right shoulder melanoma, 3.1 mm.

POST-OP DIAGNOSIS: Same.

PROCEDURE: WLE with lymph node biopsy and axillary dissection.

ICD-0-3
Melanoma, NOS 8720/3 12/15/10 per

Site code: Shoulder, Skin C44.6

FINAL DIAGNOSIS:

PART 1: SKIN AND SUBCUTANEOUS TISSUE, RIGHT SHOULDER, WIDE LOCAL EXCISION -

- A. NO RESIDUAL MELANOCYTIC LESION OR MALIGNANCY SEEN.
- B. SCAR OF SKIN WITH SUTURE GRANULOMAS, ACUTE AND CHRONIC INFLAMMATION WITH FOREIGN BODY GIANT CELL REACTION AND FAT NECROSIS.
- C. MARGINS OF RESECTION FREE OF NEOPLASM.

PART 2: LYMPH NODE, RIGHT SENTINEL #1, BIOPSY -

ONE (1) BENIGN LYMPH NODE, NEGATIVE FOR METASTATIC MELANOMA (0/1) (see comment).

PART 3: LYMPH NODES, RIGHT AXILLARY CONTENTS, DISSECTION -

METASTATIC MALIGNANT MELANOMA IN ONE (1) OF SEVEN (7) LYMPH NODES, CONFINED WITHIN, IN PART NECROTIC, 2.2 CM. (1/7) (see comment).

COMMENT:

Part 2: A panel of immunostains (CD 68, HMB 45, melan A, S100 and tyrosinase) was performed on the sentinel lymph node (block 2A). All the melanoma markers are negative except for CD68, which is positive in macrophages, and S100 in dendritic cells.

Part 3: The positive large lymph node shows more or less complete replacement by metastatic malignant melanoma. The capsule is seen at places which is intact with reactive changes around. However some areas show no capsule with tumor at the cut margin suggestive of previous sectioning observed on gross examination. The remaining nodes are small and free of neoplasm.

Source: NCI Genomic Data Commons file d3621fdf-cc92-4be6-97e8-79b76b922433 (TCGA-ER-A19O.11852245-286C-47F4-A97B-A83A6441348B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).